Somatic mutation profile of tumor specimen TCGA-2A-AAYF-01A (aliquot TCGA-2A-AAYF-01A-11D-A41K-08) from TCGA case TCGA-2A-AAYF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,866 days).
Specimen TCGA-2A-AAYF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c391974d-4aab-4571-bdcc-ebdd969a7de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-AAYF-10A (Blood Derived Normal), aliquot TCGA-2A-AAYF-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9b5d027-de61-4c42-8d1f-b67063983857

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, 5'Flank 1, IGR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.8590G>A p.D2864N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99374727; called by muse, mutect2, varscan2
- H4C2 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs989958532, COSV99775111; called by muse, mutect2, varscan2
- HSP90AA1 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99355486, COSV99355572; called by muse, varscan2
- KDM7A | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775195433, COSV50090519; called by muse, mutect2
- MCMDC2 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100552264, COSV58040794; called by muse, mutect2, varscan2
- NSMAF | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as rs758487950, COSV99233358; called by muse, mutect2, varscan2
- SCN3A | c.4399A>G p.I1467V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV99328267; called by muse, mutect2, varscan2
- SNTB1 | c.518A>G p.H173R | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101180099; called by muse, mutect2, varscan2
- UIMC1 | c.1114A>G p.K372E | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs755409087, COSV101022209; called by muse, mutect2, varscan2
- UTP20 | c.5831A>G p.K1944R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV99882397; called by muse, mutect2, varscan2
- WASF1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99661460; called by muse, mutect2, varscan2
- WDR7 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99590234; called by muse, mutect2, varscan2
- ZFHX4 | c.8545C>T p.P2849S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99266719; called by muse, mutect2, varscan2
- AEBP1 | c.495G>A p.P165= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs144974496; called by muse, mutect2, varscan2
- FOXG1 | c.1392G>A p.T464= | Silent (SNP) | VAF 60/136 reads (44%) | catalogued as COSV100487032, COSV57397713; called by muse, mutect2, varscan2
- GRM8 | c.447C>T p.G149= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs749784263, COSV58844342; called by muse, mutect2, varscan2
- LIMCH1 | c.846G>A p.A282= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs139697872; called by muse, mutect2, varscan2
- MUC5AC | c.1359C>T p.H453= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs761934256, COSV100650673; called by muse, mutect2, varscan2
- MYPN | c.3591C>T p.G1197= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs876657538, COSV100590499; called by muse, mutect2, varscan2
- TMEM174 | c.93C>T p.S31= | Silent (SNP) | VAF 72/172 reads (42%) | catalogued as rs140016650; called by muse, varscan2
- TTN | c.24858G>A p.S8286= (on ENST00000591111; = p.S7359= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs369099681, COSV60005879; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- POLQ | chr3:121546426 C>A | 5'Flank (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- Unknown | chr21:16194594 A>G | IGR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221334 G>C | 3'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
